FM case AD12502 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mucoepidermoid Neoplasms; Primary site: Other and unspecified major salivary glands.
https://portal.gdc.cancer.gov/cases/3449c113-7b8a-4048-b51b-bb0b03aad4ce

Male, 81.4 years: Mucoepidermoid carcinoma (ICD-O-3 8430/3) of the major salivary gland; primary biopsied or resected from the major salivary gland. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
